Somatic mutation profile of tumor specimen TCGA-AX-A3FW-01A (aliquot TCGA-AX-A3FW-01A-11D-A228-09) from TCGA case TCGA-AX-A3FW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 66.9 years (24,419 days).
Specimen TCGA-AX-A3FW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ef50a57-3c94-450a-8f85-9f73f0293942.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3FW-10A (Blood Derived Normal), aliquot TCGA-AX-A3FW-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78f574eb-549a-4cec-9c86-6aa69bfb9361

The open-access MAF lists 55 somatic variants for this specimen: 40 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 36, Silent 15, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.885_886del p.C296* | Frame Shift Del (DEL) | VAF 31/44 reads (70%) | catalogued as rs1564568350; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 30/37 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5443G>A p.A1815T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs951446394, COSV101329948; called by muse, mutect2, varscan2
- AQR | c.3517T>G p.L1173V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV99333326; called by muse, mutect2, varscan2
- CAMK2G | c.1191G>C p.R397S (on ENST00000423381 / NM_001367518.1; = p.S395= on NM_172171.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99989486; called by muse, mutect2, varscan2
- CCDC88C | c.3977G>A p.R1326H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs758005836, COSV66240895; called by muse, mutect2, varscan2
- CD9 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs746317738, COSV99152803; called by muse, mutect2, varscan2
- CRHR2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746635689, COSV59265097; called by muse, mutect2, varscan2
- CTNND2 | c.1943C>T p.T648M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs774668411, COSV100472679; called by muse, mutect2, varscan2
- DNAH8 | c.10942G>T p.G3648C | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV100543579; called by muse, mutect2, varscan2
- DPYD | c.2576A>G p.H859R | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV100928754; called by muse, mutect2, varscan2
- GALM | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99697021; called by muse, mutect2, varscan2
- GNAI3 | c.156G>T p.Q52H | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1209959386, COSV100879832; called by muse, mutect2, varscan2
- HR | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100455661; called by muse, mutect2, varscan2
- IDS | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.559); catalogued as COSV100557859; called by muse, mutect2, varscan2
- KCNJ5 | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232257803, COSV100610569; called by muse, mutect2, varscan2
- KLHDC2 | c.662A>T p.H221L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100026887, COSV53586929; called by muse, mutect2, varscan2
- MAGEB6B | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV101301710; called by muse, mutect2, varscan2
- MBD3L2 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs776671286, COSV100421431; called by muse, mutect2, varscan2
- NALCN | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188144130, COSV51918402, COSV99216118; called by muse, mutect2, varscan2
- NEU2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs144970536; called by muse, mutect2, varscan2
- OR10A3 | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100660231, COSV62459800; called by muse, mutect2, varscan2
- OR51I1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100970755, COSV100971807; called by muse, mutect2, varscan2
- PIGU | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99465983; called by muse, mutect2, varscan2
- PKHD1 | c.5832C>A p.D1944E | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753429413, COSV61881295; called by muse, mutect2, varscan2
- PRUNE2 | c.8716A>T p.I2906F | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245420348, COSV99795899; called by muse, mutect2, varscan2
- RTF1 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs746112769, COSV101047626; called by muse, mutect2, varscan2
- SCAF1 | c.3445G>A p.A1149T | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.975); catalogued as COSV100566812; called by muse, mutect2, varscan2
- SLC16A7 | c.67G>T p.V23F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99676216, COSV99676654; called by muse, mutect2, varscan2
- SND1 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as rs769312847, COSV100689852; called by muse, mutect2, varscan2
- SPAG17 | c.184C>G p.R62G | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100308170, COSV60468876; called by muse, mutect2, varscan2
- SPINT1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100688911; called by muse, mutect2, varscan2
- STX2 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV99892450; called by muse, mutect2, varscan2
- SYT6 | c.720T>A p.D240E (on ENST00000610222 / NM_001366225.1; = p.D155E on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV101059612; called by muse, mutect2, varscan2
- TMEM187 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1199070101, COSV100890148; called by muse, mutect2, varscan2
- VWA5A | c.1879G>T p.G627C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.293); catalogued as COSV100827735; called by muse, mutect2, varscan2
- ZFHX4 | c.8714C>T p.A2905V | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99257447; called by muse, mutect2, varscan2
- ZIM3 | c.533C>A p.S178* | Nonsense Mutation (SNP) | VAF 39/77 reads (51%) | catalogued as COSV99517755; called by muse, mutect2, varscan2
- IGHG1 | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- PIK3R1 | c.1365_1367del p.Q455_F456delinsH (on ENST00000521381 / NM_181523.3; = p.Q185_F186delinsH on NM_181504.4) | In Frame Del (DEL) | VAF 20/41 reads (49%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.4755C>T p.N1585= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV101238998; called by muse, mutect2, varscan2
- AK9 | c.5061C>T p.N1687= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV101413935; called by muse, mutect2, varscan2
- APCDD1 | c.1080C>T p.T360= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs764361338, COSV62373206; called by muse, mutect2, varscan2
- ATP9A | c.2229C>T p.Y743= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as rs748863390, COSV58770009; called by muse, mutect2, varscan2
- CNKSR2 | c.2616A>G p.Q872= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV99667524; called by muse, mutect2, varscan2
- FRMPD3 | c.2664C>T p.G888= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs747060737, COSV52189187; called by muse, mutect2, varscan2
- GSG1L | c.909A>G p.P303= (on ENST00000447459 / NM_001109763.2; = p.P148= on NM_144675.2) | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV101093512; called by muse, mutect2, varscan2
- IFNL3 | c.486A>C p.P162= | Silent (SNP) | VAF 57/129 reads (44%) | catalogued as rs544442278, COSV101308011; called by muse, mutect2, varscan2
- KDM6A | c.4167A>G p.Q1389= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs753713461, COSV100937943, COSV65042355; called by muse, mutect2, varscan2
- MTUS2 | c.1410G>A p.L470= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as COSV70916875; called by muse, mutect2, varscan2
- MYOM2 | c.231G>A p.T77= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs778345982, COSV50739112; called by muse, mutect2, varscan2
- OR2M4 | c.414G>A p.P138= | Silent (SNP) | VAF 55/104 reads (53%) | catalogued as rs571067390, COSV100141225, COSV60707635; called by muse, mutect2, varscan2
- POM121L12 | c.165G>T p.L55= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs374979505, COSV101374860, COSV68693732; called by muse, mutect2, varscan2
- STAT4 | c.2040C>T p.C680= | Silent (SNP) | VAF 45/50 reads (90%) | catalogued as rs368928990, COSV61828842; called by muse, mutect2, varscan2
- UNC5D | c.2061C>T p.A687= | Silent (SNP) | VAF 44/84 reads (52%) | catalogued as rs754886431, COSV54783747; called by muse, mutect2, varscan2
